Somatic mutation profile of tumor specimen 0DKPXE from CCDI case PBBYBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,125 days).
Specimen 0DKPXE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a28c644d-0020-4901-9fd0-039f9dca313f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPWB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85550646-54ec-4c09-a811-99b1bad63d64

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 3, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 35/526 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs121918005, CM920016; ClinVar: pathogenic; called by muse, mutect2
- ALPL | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 54/888 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.958); catalogued as rs149889416, CM043964; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AHNAK2 | c.5206G>A p.G1736S | Missense Mutation (SNP) | VAF 210/513 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.509); catalogued as rs759209382; called by muse, mutect2, varscan2
- BMP7 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 60/728 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749392235, COSV67782449; called by muse, mutect2
- CCSER1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 70/672 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748961219, COSV61443763; called by muse, mutect2
- EIF4G1 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 64/609 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs912461425; called by muse, mutect2, varscan2
- FAM234B | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 272/714 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs145853473; called by muse, mutect2
- HELZ2 | c.6037G>A p.E2013K (on ENST00000467148 / NM_001037335.2; = p.E1444K on NM_033405.3) | Missense Mutation (SNP) | VAF 201/599 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs769702510; called by muse, mutect2, varscan2
- IGSF9B | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 182/440 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs756219238, COSV100316869; called by muse, mutect2, varscan2
- JPH2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 187/472 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs1332354579, COSV100881556; called by muse, mutect2, varscan2
- KIF19 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 34/1024 reads (3%) | catalogued as rs1395317066, COSV63430083; called by muse, mutect2
- MUC5B | c.14444C>T p.T4815M | Missense Mutation (SNP) | VAF 457/1057 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs199943848; called by muse, mutect2, varscan2
- OR1I1 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 200/513 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs777627724; called by muse, mutect2, varscan2
- PCDHAC1 | c.2653G>A p.G885R | Missense Mutation (SNP) | VAF 226/550 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs900919931, COSV53842646; called by muse, mutect2, varscan2
- SLC15A5 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 232/537 reads (43%) | catalogued as rs962046049, COSV61364547; called by muse, mutect2, varscan2
- ST8SIA5 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 186/647 reads (29%) | PolyPhen probably damaging (0.977); catalogued as rs781355343, COSV59330431; called by muse, mutect2, varscan2
- TRIM29 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 210/540 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs376084869; called by muse, varscan2
- CNFN | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 75/929 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- ECH1 | c.260+2T>C p.X87_splice | Splice Site (SNP) | VAF 127/359 reads (35%) | called by muse, mutect2, varscan2
- LRRC34 | c.83dup p.A29Gfs*31 | Frame Shift Ins (INS) | VAF 211/621 reads (34%) | called by mutect2, pindel, varscan2
- PM20D1 | c.1350C>G p.F450L | Missense Mutation (SNP) | VAF 310/766 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- FBRSL1 | c.2106C>T p.G702= | Silent (SNP) | VAF 37/672 reads (6%) | called by muse, mutect2
- GFM1 | c.403C>T p.L135= | Silent (SNP) | VAF 48/614 reads (8%) | catalogued as COSV51835167; called by muse, mutect2
- GREB1L | c.3528C>T p.A1176= | Silent (SNP) | VAF 32/470 reads (7%) | catalogued as rs114233250; called by muse, mutect2
- HMGCR | c.681C>T p.R227= | Silent (SNP) | VAF 222/570 reads (39%) | catalogued as rs775353521; called by muse, mutect2, varscan2
- PCDHA1 | c.1854G>A p.A618= | Silent (SNP) | VAF 54/829 reads (7%) | catalogued as rs543937372, COSV65374214; called by muse, mutect2
- PROSER3 | c.1149G>A p.P383= | Silent (SNP) | VAF 39/592 reads (7%) | catalogued as rs772441899; called by muse, mutect2
- RSPO4 | c.243C>T p.R81= | Silent (SNP) | VAF 31/469 reads (7%) | catalogued as rs756916549, COSV54080461; called by muse, mutect2
- SLC9A2 | c.825C>T p.I275= | Silent (SNP) | VAF 614/725 reads (85%) | catalogued as rs1431914223, COSV52131232; called by muse, mutect2, varscan2
- USP47 | c.372T>C p.F124= (on ENST00000399455 / NM_001372095.1; = p.F36= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 185/490 reads (38%) | called by muse, mutect2, varscan2
- FCHSD1 | c.706-64C>T | Intron (SNP) | VAF 42/101 reads (42%) | catalogued as rs568319196; called by muse, mutect2, varscan2
- KIF1B | c.2115+7164C>T | Intron (SNP) | VAF 69/537 reads (13%) | called by muse, mutect2, varscan2
- POLR1B | c.1613-39G>A | Intron (SNP) | VAF 42/93 reads (45%) | catalogued as rs1311513913; called by muse, mutect2, varscan2
- SPATA31D1 | c.*10T>G | 3'UTR (SNP) | VAF 168/376 reads (45%) | called by muse, mutect2, varscan2
